Gene-level copy-number profile of tumor specimen C3N-00340-03 from CPTAC case C3N-00340, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.7 years (22,158 days).
Specimen C3N-00340-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f0aaab2-2e54-43e3-a82c-5cffd6706566.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00340-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/04ff9638-6487-4176-8a25-e78a02c9ba1c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 2,806; copy number 2: 23,441; copy number 3: 23,247; copy number 4: 7,896; copy number 5: 460; copy number 6: 246; copy number 7: 30; copy number 8: 156; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr21:13,047,583–13,047,689, 1 gene (within-gene range 0–1): RNU6-614P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 188 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes, copy number 7: AC239800.3, LINC02591, RNU1-143P.
- chr6:11,414,636–11,515,710, 2 genes, copy number 9 (within-gene range 5–9): AL445430.2, AL445430.1.
- chr9:61,581,813–61,627,683, 2 genes, copy number 7: AL935212.3, FAM242D.
- chr11:48,420,210–49,434,438, 37 genes, copy number 7–8: OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1, TYRL, CBX3P8, AC135977.1.
- chr17:28,041,737–28,861,966, 76 genes, copy number 8 (broad region; genes not listed).
- chr17:47,967,810–48,123,601, 11 genes, copy number 8 (within-gene range 2–8): CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11.
- chr19:5,674,947–5,978,142, 21 genes, copy number 8: RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3.
- chr19:7,958,573–8,005,659, 1 gene, copy number 7 (within-gene range 4–7): ELAVL1.
- chr19:8,052,767–8,343,262, 10 genes, copy number 7 (within-gene range 4–7): CCL25, FBN3, AC022146.1, CERS4, AC022146.2, CD320, AC010323.1, NDUFA7, RPS28, KANK3.
- chr19:37,312,837–37,855,215, 25 genes, copy number 8: ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1.

Autosomal genes at a single copy (total copy number 1): 1,436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
